Gene-level copy-number profile of tumor specimen C3L-05335-54 from CPTAC case C3L-05335, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 42.6 years (15,545 days).
Specimen C3L-05335-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f8c2d011-1ee0-4cf1-8722-4d7085c11e11.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05335-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/9d027f22-57c4-4d33-8052-230f693a119f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 10; copy number 2: 58,371; copy number 3: 4; copy number 5: 10.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:86,649–207,428, 10 genes (within-gene range 0–2): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3, AC069287.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:177,301,198–177,372,596, 6 genes, copy number 5: RAB24, MXD3, PRELID1, LMAN2, AC146507.1, RGS14.
- chr11:3,797,724–3,855,509, 3 genes, copy number 5 (within-gene range 2–5): PGAP2, RHOG, STIM1-AS1.
- chr11:3,854,612–3,855,399, 1 gene, copy number 5 (within-gene range 2–5): AC090587.1.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
